Surgical pathology report (de-identified scan), TCGA case TCGA-FL-A1YT, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma), tissue source site University of Hawaii - Normal Study, specimen TCGA-FL-A1YT-11A (Solid Tissue Normal).

[page 1 of 2]
Surgical Pathology Report

Patient Name: [REDACTED]
Med. Rec. #: [REDACTED]
DOB: [REDACTED]
Gender: [REDACTED]
Physician(s): [REDACTED]
cc: [REDACTED]

Client: [REDACTED]
Location: [REDACTED]

Accession #: [REDACTED]
Taken: [REDACTED]
Received: [REDACTED]
Reported: [REDACTED]

History/Clinical Dx: Pelvic mass

Postoperative Dx: Same, pending pathology examination

Specimen(s) Received:

- A: Right ovary (frozen section)
- B: Umbilical hernia sac
- C: Uterus, cervix and right fallopian tube

ICD-0-3 not applicable.

*Normal path from non-cancer patient.
As 11/11*

DIAGNOSIS:

A. Right ovary:

1. Benign serous cystadenoma, ovary
2. Fallopian tube with no pathologic change

B. Umbilical hernia sac:

Fibroadipose tissue consistent with hernia sac

C. Uterus and cervix:

Cervix: Unremarkable
Endometrium: Weakly proliferative
Myometrium: 1. Adenofibroma
2. Adenomyosis

Intraoperative Consultation:

A. Frozen section: Benign

Gross Description

- A. Submitted fresh as "right ovary" is a cystically dilated ovary and adjacent fallopian tube. The ovary measures approximately 7.0 x 4.0 x 3.2 cm in greatest dimension. The external surface is smooth. Sectioning the ovary reveals multiple locules containing gold colored clear fluid. The lining of the loculations is predominantly smooth with a few small firm polypoid nodules measuring up to 0.2 cm. The attached fallopian tube measures approximately 4.0 cm in length and is grossly unremarkable. Representative sections are submitted in seven cassettes with the frozen section residual in cassette A1.

Disclaimer Statement:

The following statement may be applicable to some of the information contained herein: This report was prepared and its contents are based on information received from the patient's medical records and the patient's history. The information is not intended to be a substitute for a clinical examination. The information is not intended to be a substitute for a clinical examination. The information is not intended to be a substitute for a clinical examination.

Page 1 of 2

[page 2 of 2]
Surgical Pathology Report

- B. Submitted as "umbilical hernia sac" is a single fragment of membranous fibrofatty tissue measuring up to 6.0 cm in greatest dimension. A representative section is submitted in one cassette.
- C. Submitted as "uterus, cervix, and right fallopian tube" is a uterus with attached cervix, which has been opened longitudinally on the anterior aspect. The specimen weighs 49 gms and measures 7.3 x 3.8 x 2.5 cm in greatest dimension. The ectocervical mucosa is smooth. The endocervical canal contains no gross lesions. The endometrial cavity is lined by a smooth thin mucosa. The myometrium measures up to 1.8 cm in thickness and contains a single well-circumscribed nodule, which measures 1.7 cm. It has a area of central cystic degeneration, which contains mucoid fluid.

KEY TO CASSETTES:

C1	-	Cervix
C2&C3	-	Endometrium myometrium
C4&C5	-	Myometrial nodule

Microscopic Description

A-C. The microscopic findings support the above diagnoses.

Source: NCI Genomic Data Commons file 46ca27c7-2144-4d85-af9a-94cd98ec4050 (TCGA-FL-A1YT.4E2E650A-F057-4B4E-84FD-2ECFC6D13C4D.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).